Somatic mutation profile of tumor specimen MMRF_2377_1_BM_CD138pos (aliquot MMRF_2377_1_BM_CD138pos_T1_KHS5U_L11003) from MMRF case MMRF_2377, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.7 years (22,910 days).
Specimen MMRF_2377_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83a2a8e6-fbd5-4598-96f2-fa60995d2a28.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2377_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2377_1_PB_Whole_C2_KHS5U_L11004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0526ac0f-669b-4a8c-97cc-9c0a8dd2aee5

The open-access MAF lists 250 somatic variants for this specimen: 96 protein-altering or splice-affecting, 23 silent, 131 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 80, 3'UTR 74, Intron 27, Silent 23, 5'UTR 16, Nonsense Mutation 5, 3'Flank 5, 5'Flank 5, RNA 4, In Frame Del 3, Splice Site 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALS2 | c.2158C>T p.L720F | Missense Mutation (SNP) | VAF 130/221 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV51885616; called by muse, mutect2, varscan2
- ANKRD34B | c.235A>G p.I79V | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs781522784; called by muse, mutect2, varscan2
- CEP128 | c.293A>T p.N98I | Missense Mutation (SNP) | VAF 148/151 reads (98%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as rs749726638; called by muse, mutect2, varscan2
- CHD8 | c.5581C>A p.P1861T (on ENST00000646647 / NM_001170629.2; = p.P1582T on NM_020920.4) | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV63037324, COSV63037461; called by muse, mutect2
- DLX6 | c.498G>T p.K166N | Missense Mutation (SNP) | VAF 88/434 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99142275; called by muse, mutect2, varscan2
- DNAH6 | c.6229C>T p.R2077C | Missense Mutation (SNP) | VAF 72/272 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs576447190, COSV52849308; called by muse, varscan2
- FNDC1 | c.392-1G>A p.X131_splice | Splice Site (SNP) | VAF 35/134 reads (26%) | catalogued as rs947051579; called by muse, mutect2, varscan2
- FTSJ3 | c.1480C>T p.R494* | Nonsense Mutation (SNP) | VAF 85/261 reads (33%) | catalogued as COSV63790093; called by muse, mutect2, varscan2
- FZD7 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1326327915; called by muse, mutect2, varscan2
- HMGB4 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs760361458; called by muse, mutect2, varscan2
- IGHV2-70 | c.293A>G p.Q98R | Missense Mutation (SNP) | VAF 101/103 reads (98%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); catalogued as rs373048671; called by muse, varscan2
- IGLL5 | c.127G>A p.V43I | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs6003368, COSV73248992, COSV73250942, COSV73250989, COSV73251049; called by muse, varscan2
- IL4I1 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.93); PolyPhen benign (0.019); catalogued as COSV55580085; called by muse, mutect2, varscan2
- IQGAP2 | c.2980G>T p.D994Y | Missense Mutation (SNP) | VAF 83/112 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs138211969; called by muse, mutect2, varscan2
- ITGA2B | c.253T>C p.F85L | Missense Mutation (SNP) | VAF 125/195 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV52232958; called by muse, mutect2, varscan2
- KANK1 | c.2410G>A p.V804I | Missense Mutation (SNP) | VAF 58/181 reads (32%) | SIFT tolerated (0.38); PolyPhen benign (0.164); catalogued as COSV63212257; called by muse, mutect2, varscan2
- L1TD1 | c.2074G>A p.D692N | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as COSV100776572; called by muse, mutect2, varscan2
- LTB | c.209-3C>T | Splice Region (SNP) | VAF 55/200 reads (28%) | catalogued as rs1263391246; called by muse, mutect2, varscan2
- MAG | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 155/253 reads (61%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1304260702, COSV62700378; called by muse, mutect2, varscan2
- MCF2L | c.3185T>C p.V1062A (on ENST00000375608; = p.V1030A on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT tolerated (0.39); PolyPhen benign (0.344); catalogued as rs1207272921; called by muse, mutect2, varscan2
- MYRIP | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 86/132 reads (65%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.999); catalogued as COSV56874619; called by muse, mutect2, varscan2
- NGF | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 114/234 reads (49%) | SIFT tolerated (0.51); PolyPhen benign (0.05); catalogued as rs199511298; called by muse, mutect2, varscan2
- NOTCH1 | c.6502T>C p.C2168R | Missense Mutation (SNP) | VAF 59/177 reads (33%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.794); catalogued as rs1307591119; called by muse, mutect2, varscan2
- NUP98 | c.4732C>T p.R1578C (on ENST00000359171 / NM_001365126.1; = p.R1561C on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/93 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61431657; called by muse, mutect2, varscan2
- OR4C46 | c.106A>C p.T36P | Missense Mutation (SNP) | VAF 111/345 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.824); catalogued as COSV100060761; called by muse, mutect2, varscan2
- PIM1 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 221/314 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.267); catalogued as COSV65164498, COSV65164552, COSV65165915; called by muse, mutect2, varscan2
- PROB1 | c.196G>A p.G66S | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as rs1270161721; called by muse, mutect2, varscan2
- RANBP9 | c.433_435del p.K145del | In Frame Del (DEL) | VAF 85/160 reads (53%) | catalogued as rs1269145391; called by mutect2, pindel, varscan2
- RAPGEF2 | c.3709G>A p.A1237T | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.014); catalogued as rs1421265498, COSV52430298; called by muse, mutect2, varscan2
- ROBO1 | c.1018G>A p.E340K | Missense Mutation (SNP) | VAF 76/704 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71396756; called by muse, mutect2, varscan2
- SAFB2 | c.2764_2778del p.L922_G926del | In Frame Del (DEL) | VAF 75/127 reads (59%) | catalogued as rs749079142; called by mutect2, varscan2
- SRGAP2B | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1339566865; called by muse, mutect2, varscan2
- TTC21A | c.3541C>T p.R1181C | Missense Mutation (SNP) | VAF 121/197 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs760939060, COSV56187947; called by muse, mutect2, varscan2
- XIRP2 | c.622G>T p.E208* (on ENST00000628543; = p.E383* on NM_152381.6) | Nonsense Mutation (SNP) | VAF 67/200 reads (34%) | catalogued as COSV99747316; called by muse, mutect2, varscan2
- ZMYM4 | c.2306G>A p.G769E | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58916684; called by muse, mutect2, varscan2
- ZNF468 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 158/239 reads (66%) | SIFT tolerated (0.17); PolyPhen benign (0.17); catalogued as rs753279618, COSV54693421; called by muse, mutect2, varscan2
- ZNF776 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 66/102 reads (65%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs774740912, COSV57814343; called by muse, mutect2, varscan2
- ABCC9 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 209/334 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- ACOXL | c.622T>G p.F208V | Missense Mutation (SNP) | VAF 113/178 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- ADH7 | c.1099del p.I367Sfs*18 | Frame Shift Del (DEL) | VAF 40/98 reads (41%) | called by mutect2, pindel, varscan2
- AMOT | c.2381C>T p.A794V (on ENST00000371959 / NM_001113490.1; = p.A385V on NM_133265.3) | Missense Mutation (SNP) | VAF 82/82 reads (100%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- ANXA2 | c.233G>A p.R78K | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT tolerated (0.72); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BEND7 | c.1143dup p.Q382Afs*35 | Frame Shift Ins (INS) | VAF 71/195 reads (36%) | called by mutect2, pindel, varscan2
- C1orf94 | c.473C>A p.A158D | Missense Mutation (SNP) | VAF 111/240 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.625); called by muse, mutect2, varscan2
- CA10 | c.250C>G p.P84A | Missense Mutation (SNP) | VAF 63/204 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CD48 | c.366G>T p.K122N | Missense Mutation (SNP) | VAF 129/478 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- CXCR2 | c.788G>A p.C263Y | Missense Mutation (SNP) | VAF 72/264 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- CXCR2 | c.789C>G p.C263W | Missense Mutation (SNP) | VAF 72/266 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- DAOA | c.169A>T p.R57W | Missense Mutation (SNP) | VAF 179/384 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DDX3Y | c.1879G>A p.G627S | Missense Mutation (SNP) | VAF 53/56 reads (95%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DDX59 | c.1285A>T p.K429* | Nonsense Mutation (SNP) | VAF 112/186 reads (60%) | called by muse, mutect2, varscan2
- GALNT17 | c.1738G>T p.D580Y | Missense Mutation (SNP) | VAF 125/205 reads (61%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- GPT | c.1265del p.P422Rfs*47 | Frame Shift Del (DEL) | VAF 59/147 reads (40%) | called by mutect2, pindel, varscan2
- IFRD1 | c.1331G>C p.R444T | Missense Mutation (SNP) | VAF 127/236 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- INCA1 | c.272G>T p.R91I (on ENST00000574617 / NM_001167986.1; = p.R76I on NM_213726.2) | Missense Mutation (SNP) | VAF 151/233 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- INO80 | c.1028T>A p.M343K | Missense Mutation (SNP) | VAF 91/136 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- ITGA2 | c.2994A>C p.K998N | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- KPNB1 | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 47/145 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LIMCH1 | c.1678G>C p.V560L | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- LONRF2 | c.989G>T p.S330I | Missense Mutation (SNP) | VAF 178/269 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRIQ1 | c.1606A>C p.K536Q | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LRRN3 | c.514A>C p.N172H | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- MICAL3 | c.1652T>C p.L551S | Missense Mutation (SNP) | VAF 78/147 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MUC6 | c.4300C>G p.P1434A | Missense Mutation (SNP) | VAF 113/236 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- MYH6 | c.2880G>T p.E960D | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- NAALADL2 | c.119A>T p.D40V | Missense Mutation (SNP) | VAF 134/393 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- NFATC4 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NFKBIA | c.446dup p.H149Qfs*5 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by mutect2, pindel
- NFKBIA | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 26/205 reads (13%) | called by muse, mutect2, varscan2
- OR2M2 | c.368A>C p.Y123S | Missense Mutation (SNP) | VAF 121/198 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- PCDH11Y | c.1561A>C p.S521R (on ENST00000400457 / NM_032973.2; = p.S510R on NM_032971.3) | Missense Mutation (SNP) | VAF 104/107 reads (97%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLK2 | c.51G>A p.M17I | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, mutect2
- PTPRQ | c.23A>C p.N8T | Missense Mutation (SNP) | VAF 61/454 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- RFTN1 | c.626A>T p.D209V | Missense Mutation (SNP) | VAF 93/325 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- RTN4RL1 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 97/150 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- SELENOI | c.316G>T p.V106L | Missense Mutation (SNP) | VAF 132/223 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); called by muse, mutect2, varscan2
- SH3BP4 | c.206C>A p.T69N | Missense Mutation (SNP) | VAF 71/229 reads (31%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- SH3GL2 | c.188-1G>C p.X63_splice | Splice Site (SNP) | VAF 35/101 reads (35%) | called by muse, mutect2, varscan2
- SIPA1L2 | c.3607G>T p.G1203* | Nonsense Mutation (SNP) | VAF 83/279 reads (30%) | called by muse, mutect2, varscan2
- SLITRK1 | c.1864C>T p.P622S | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.474); called by muse, mutect2, varscan2
- SOX9 | c.593T>C p.I198T | Missense Mutation (SNP) | VAF 233/366 reads (64%) | SIFT tolerated (0.4); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- STK38 | c.1173-2A>T p.X391_splice | Splice Site (SNP) | VAF 17/57 reads (30%) | called by muse, mutect2, varscan2
- STYX | c.80_82del p.R27_E28delinsQ | In Frame Del (DEL) | VAF 43/129 reads (33%) | called by mutect2, pindel, varscan2
- SYNE1 | c.10945A>C p.T3649P (on ENST00000367255 / NM_182961.4; = p.T3634P on NM_033071.3) | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- TASOR2 | c.6263T>G p.V2088G | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TMEM132D | c.2398A>G p.N800D | Missense Mutation (SNP) | VAF 152/229 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- TNRC6B | c.5017C>T p.P1673S (on ENST00000454349 / NM_001162501.2; = p.P1563S on NM_015088.3) | Missense Mutation (SNP) | VAF 124/264 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRAF3 | c.293A>G p.D98G | Missense Mutation (SNP) | VAF 219/220 reads (100%) | SIFT deleterious (0.03); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TRIM47 | c.1726A>C p.K576Q | Missense Mutation (SNP) | VAF 81/297 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TSEN34 | c.877C>A p.P293T | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); called by muse, mutect2
- UGT3A1 | c.612T>G p.F204L | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- VIPR2 | c.349G>A p.E117K | Missense Mutation (SNP) | VAF 7/109 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2
- VPS13B | c.8260G>C p.G2754R | Missense Mutation (SNP) | VAF 42/381 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- WDR87 | c.3105T>A p.N1035K | Missense Mutation (SNP) | VAF 83/234 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- WRN | c.3367A>G p.N1123D | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WRN | c.3368A>C p.N1123T | Missense Mutation (SNP) | VAF 43/142 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AMER1 | c.2601C>T p.S867= | Silent (SNP) | VAF 27/80 reads (34%) | called by muse, mutect2, varscan2
- ARHGEF37 | c.858G>A p.L286= | Silent (SNP) | VAF 26/139 reads (19%) | called by muse, mutect2, varscan2
- BIRC6 | c.9864C>T p.A3288= | Silent (SNP) | VAF 62/192 reads (32%) | called by muse, mutect2, varscan2
- C1orf116 | c.1269A>G p.G423= | Silent (SNP) | VAF 54/148 reads (36%) | catalogued as rs371432769; called by muse, mutect2, varscan2
- CCDC40 | c.1239C>T p.D413= | Silent (SNP) | VAF 49/168 reads (29%) | catalogued as rs751991087; ClinVar: likely benign; called by muse, mutect2, varscan2
- CSMD3 | c.1719A>G p.Q573= (on ENST00000297405 / NM_001363185.1; = p.Q469= on NM_052900.3) | Silent (SNP) | VAF 242/365 reads (66%) | called by muse, mutect2, varscan2
- CYGB | c.189C>T p.F63= | Silent (SNP) | VAF 52/270 reads (19%) | called by muse, mutect2, varscan2
- GLOD4 | c.837T>C p.L279= (on ENST00000301328 / NM_001366247.1; = p.L264= on NM_016080.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 263/415 reads (63%) | catalogued as rs1413185533; called by muse, mutect2, varscan2
- IGKV2D-28 | c.102C>T p.T34= | Silent (SNP) | VAF 15/44 reads (34%) | called by mutect2, varscan2
- IGLL5 | c.81G>C p.L27= | Silent (SNP) | VAF 30/30 reads (100%) | catalogued as rs56055217, COSV73249379; called by muse, varscan2
- L1TD1 | c.2457T>C p.F819= | Silent (SNP) | VAF 48/96 reads (50%) | called by muse, mutect2, varscan2
- MYO15A | c.1938G>A p.A646= | Silent (SNP) | VAF 8/26 reads (31%) | called by muse, mutect2, varscan2
- NAPRT | c.1248G>A p.T416= | Silent (SNP) | VAF 46/122 reads (38%) | catalogued as rs143442304; called by muse, mutect2, varscan2
- OR4A5 | c.525T>C p.S175= | Silent (SNP) | VAF 145/230 reads (63%) | called by muse, mutect2, varscan2
- OR8K3 | c.196C>T p.L66= | Silent (SNP) | VAF 36/349 reads (10%) | called by muse, mutect2, varscan2
- PROB1 | c.3015C>G p.T1005= | Silent (SNP) | VAF 87/140 reads (62%) | called by muse, mutect2, varscan2
- PYDC2 | c.213A>G p.A71= | Silent (SNP) | VAF 150/440 reads (34%) | catalogued as rs779414599; called by muse, mutect2
- RBPMS | c.102T>C p.D34= | Silent (SNP) | VAF 257/387 reads (66%) | called by muse, mutect2, varscan2
- RPL10 | c.39G>A p.K13= | Silent (SNP) | VAF 94/95 reads (99%) | catalogued as rs782767297; called by muse, mutect2, varscan2
- SNX7 | c.954G>A p.K318= | Silent (SNP) | VAF 22/127 reads (17%) | catalogued as rs769472198; called by muse, mutect2, varscan2
- TIMM50 | c.1020C>G p.G340= | Silent (SNP) | VAF 66/207 reads (32%) | called by muse, mutect2, varscan2
- TSEN2 | c.258T>C p.V86= | Silent (SNP) | VAF 41/61 reads (67%) | called by muse, mutect2, varscan2
- ZYX | c.189T>C p.I63= | Silent (SNP) | VAF 107/159 reads (67%) | catalogued as COSV100503754; called by muse, mutect2, varscan2
- AC022415.2 | c.*1996G>A | 3'UTR (SNP) | VAF 268/814 reads (33%) | called by muse, mutect2, varscan2
- AC104825.1 | n.1674G>A | RNA (SNP) | VAF 53/221 reads (24%) | called by muse, mutect2, varscan2
- ADCYAP1 | c.*351A>G | 3'UTR (SNP) | VAF 14/31 reads (45%) | called by muse, mutect2, varscan2
- AIG1 | chr6:143339881 A>G | 3'Flank (SNP) | VAF 70/107 reads (65%) | called by muse, mutect2, varscan2
- AR | c.*4348dup | 3'UTR (INS) | VAF 16/26 reads (62%) | catalogued as rs397737842; called by pindel, varscan2
- ARID1A | c.-319C>T | 5'UTR (SNP) | VAF 30/74 reads (41%) | catalogued as rs1315690472; called by muse, mutect2, varscan2
- ARL13B | c.*211C>T | 3'UTR (SNP) | VAF 13/136 reads (10%) | called by muse, mutect2
- ATP5F1A | c.1176+164C>G | Intron (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021290 A>T | 5'Flank (SNP) | VAF 132/206 reads (64%) | called by muse, mutect2, varscan2
- BCL7A | chr12:122021497 A>C | 5'Flank (SNP) | VAF 64/186 reads (34%) | called by muse, mutect2, varscan2
- C11orf71 | c.*69T>C | 3'UTR (SNP) | VAF 40/63 reads (63%) | called by muse, mutect2, varscan2
- C1orf141 | c.*488C>T | 3'UTR (SNP) | VAF 33/98 reads (34%) | called by muse, mutect2, varscan2
- C20orf96 | c.-5C>T | 5'UTR (SNP) | VAF 70/211 reads (33%) | called by muse, mutect2, varscan2
- C5orf52 | c.*84G>A | 3'UTR (SNP) | VAF 49/143 reads (34%) | catalogued as rs1322419153; called by muse, mutect2, varscan2
- C8orf86 | n.876A>T | RNA (SNP) | VAF 26/138 reads (19%) | called by muse, mutect2, varscan2
- CA5B | c.*3785C>A | 3'UTR (SNP) | VAF 24/24 reads (100%) | catalogued as COSV57066890; called by muse, mutect2, varscan2
- CD72 | c.-108_-107del | 5'UTR (DEL) | VAF 296/571 reads (52%) | called by mutect2, pindel, varscan2
- CDC42EP3 | c.*312T>A | 3'UTR (SNP) | VAF 12/170 reads (7%) | called by muse, mutect2
- CLCN7 | c.*1163C>G | 3'UTR (SNP) | VAF 78/158 reads (49%) | catalogued as rs984493643; called by muse, mutect2, varscan2
- CLDN16 | c.*1627A>G | 3'UTR (SNP) | VAF 32/94 reads (34%) | called by muse, mutect2, varscan2
- CLEC5A | c.*768del | 3'UTR (DEL) | VAF 26/137 reads (19%) | called by mutect2, pindel, varscan2
- COL3A1 | c.*466dup | 3'UTR (INS) | VAF 102/173 reads (59%) | called by mutect2, varscan2
- COL4A1 | c.*1266A>T | 3'UTR (SNP) | VAF 44/87 reads (51%) | called by muse, mutect2, varscan2
- CSE1L | c.*332T>C | 3'UTR (SNP) | VAF 32/69 reads (46%) | called by muse, mutect2, varscan2
- CYFIP1 | chr15:22868287 C>G | 3'Flank (SNP) | VAF 12/81 reads (15%) | called by muse, mutect2, varscan2
- DCLK2 | c.-146G>A | 5'UTR (SNP) | VAF 33/58 reads (57%) | catalogued as rs553753837; called by muse, mutect2, varscan2
- DOCK1 | c.*56C>G | 3'UTR (SNP) | VAF 166/390 reads (43%) | called by muse, mutect2, varscan2
- DPP6 | c.-19G>T | 5'UTR (SNP) | VAF 152/548 reads (28%) | catalogued as rs1264755004; called by muse, mutect2
- DST | c.20247+102G>T | Intron (SNP) | VAF 12/16 reads (75%) | called by muse, varscan2
- DTWD2 | c.*2389T>C | 3'UTR (SNP) | VAF 13/16 reads (81%) | called by muse, mutect2, varscan2
- DTX1 | c.-280T>G | 5'UTR (SNP) | VAF 46/166 reads (28%) | called by muse, varscan2
- DTX1 | c.-148A>G | 5'UTR (SNP) | VAF 72/126 reads (57%) | called by muse, varscan2
- DTX1 | c.-78A>C | 5'UTR (SNP) | VAF 48/85 reads (56%) | called by muse, mutect2, varscan2
- ELAPOR2 | c.*2574C>A | 3'UTR (SNP) | VAF 43/151 reads (28%) | called by muse, mutect2, varscan2
- ETNK2 | c.-142G>A | 5'UTR (SNP) | VAF 39/65 reads (60%) | called by muse, mutect2, varscan2
- FHL1 | c.-242-12del | Intron (DEL) | VAF 69/96 reads (72%) | catalogued as rs1231947503; called by mutect2, pindel, varscan2
- FIGN | c.*6926T>A | 3'UTR (SNP) | VAF 17/40 reads (43%) | catalogued as rs949782796; called by muse, varscan2
- GLB1L2 | c.*187G>A | 3'UTR (SNP) | VAF 16/120 reads (13%) | called by muse, mutect2, varscan2
- GLIPR1L2 | c.670+344A>C | Intron (SNP) | VAF 37/58 reads (64%) | called by muse, mutect2, varscan2
- GORASP2 | c.*852A>G | 3'UTR (SNP) | VAF 75/196 reads (38%) | called by muse, mutect2, varscan2
- GPC6 | chr13:93226756 G>T | 5'Flank (SNP) | VAF 14/24 reads (58%) | called by muse, mutect2, varscan2
- GPX3 | c.*106A>C | 3'UTR (SNP) | VAF 306/443 reads (69%) | called by muse, mutect2, varscan2
- H2AC8 | c.*41G>C | 3'UTR (SNP) | VAF 110/387 reads (28%) | catalogued as COSV55126619; called by muse, mutect2, varscan2
- H2BC4 | c.*9+66C>T | Intron (SNP) | VAF 154/238 reads (65%) | called by muse, mutect2, varscan2
- IGLL5 | c.-220T>C | 5'UTR (SNP) | VAF 23/23 reads (100%) | catalogued as rs1014492262; called by muse, varscan2
- IGLL5 | c.*182del | 3'UTR (DEL) | VAF 122/305 reads (40%) | called by mutect2, pindel, varscan2
- IGLON5 | c.*914C>A | 3'UTR (SNP) | VAF 230/357 reads (64%) | called by muse, varscan2
- IL16 | chr15:81311989 A>T | 3'Flank (SNP) | VAF 45/67 reads (67%) | called by muse, mutect2, varscan2
- IL18RAP | c.*53G>A | 3'UTR (SNP) | VAF 224/338 reads (66%) | called by muse, varscan2
- KCTD13 | c.415-135G>A | Intron (SNP) | VAF 8/14 reads (57%) | catalogued as rs1005681096, COSV58160004; called by muse, mutect2
- LRP12 | chr8:104484430 G>A | 3'Flank (SNP) | VAF 14/45 reads (31%) | catalogued as rs1462510220; called by muse, mutect2, varscan2
- LRRIQ3 | c.573+1788T>G | Intron (SNP) | VAF 146/308 reads (47%) | called by muse, mutect2, varscan2
- LRRN3 | c.*543A>G | 3'UTR (SNP) | VAF 6/17 reads (35%) | called by muse, mutect2, varscan2
- LRRTM3 | c.*215G>T | 3'UTR (SNP) | VAF 26/54 reads (48%) | catalogued as rs1469451350; called by muse, mutect2, varscan2
- LTB | c.163-44_163-42del | Intron (DEL) | VAF 330/598 reads (55%) | called by pindel, varscan2
- LTB | c.163-99A>G | Intron (SNP) | VAF 371/598 reads (62%) | called by muse, varscan2
- LTB | c.163-154C>T | Intron (SNP) | VAF 181/289 reads (63%) | catalogued as rs543196679; called by muse, varscan2
- LTB | c.163-179T>G | Intron (SNP) | VAF 71/208 reads (34%) | called by muse, varscan2
- LTB | c.162+124T>C | Intron (SNP) | VAF 22/76 reads (29%) | catalogued as COSV53001768; called by muse, mutect2, varscan2
- MAN2B2 | c.2932+274G>A | Intron (SNP) | VAF 70/129 reads (54%) | called by muse, mutect2, varscan2
- MECOM | c.-332dup | 5'UTR (INS) | VAF 28/114 reads (25%) | catalogued as rs758845957; called by pindel, varscan2
- MEGF10 | c.*2381C>T | 3'UTR (SNP) | VAF 19/96 reads (20%) | called by muse, mutect2, varscan2
- MIB1 | c.*1267T>C | 3'UTR (SNP) | VAF 26/39 reads (67%) | called by muse, mutect2, varscan2
- MIR5195 | n.115A>T | RNA (SNP) | VAF 41/44 reads (93%) | called by muse, varscan2
- MIR5195 | n.36A>G | RNA (SNP) | VAF 92/95 reads (97%) | catalogued as rs1479660203; called by muse, varscan2
- MMP16 | c.*6476G>A | 3'UTR (SNP) | VAF 23/89 reads (26%) | called by muse, mutect2, varscan2
- MNT | c.*2299_*2300insGCACGC | 3'UTR (INS) | VAF 23/77 reads (30%) | called by pindel, varscan2
- MTREX | c.*595G>C | 3'UTR (SNP) | VAF 11/136 reads (8%) | called by muse, mutect2
- MYD88 | c.*1639G>A | 3'UTR (SNP) | VAF 13/113 reads (12%) | called by muse, mutect2, varscan2
- MYO1E | c.-140G>C | 5'UTR (SNP) | VAF 110/168 reads (65%) | called by muse, mutect2, varscan2
- N4BP3 | c.*2610G>A | 3'UTR (SNP) | VAF 120/184 reads (65%) | called by muse, mutect2, varscan2
- NAALADL2 | c.*2294T>C | 3'UTR (SNP) | VAF 25/72 reads (35%) | called by muse, mutect2, varscan2
- NCAM2 | c.*1300A>G | 3'UTR (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- NCOA6 | c.*255A>G | 3'UTR (SNP) | VAF 58/116 reads (50%) | called by muse, mutect2, varscan2
- NIPAL4 | c.*258C>T | 3'UTR (SNP) | VAF 33/127 reads (26%) | called by muse, mutect2, varscan2
- NRXN1 | c.-351T>G | 5'UTR (SNP) | VAF 23/81 reads (28%) | called by muse, mutect2, varscan2
- NUP58 | c.*892_*894dup | 3'UTR (INS) | VAF 23/52 reads (44%) | called by mutect2, pindel, varscan2
- PCDH10 | c.*1107T>A | 3'UTR (SNP) | VAF 12/25 reads (48%) | catalogued as COSV52091381; called by muse, mutect2, varscan2
- PCDH9 | c.*1603A>C | 3'UTR (SNP) | VAF 29/62 reads (47%) | called by muse, mutect2, varscan2
- PDE10A | c.*4685A>C | 3'UTR (SNP) | VAF 75/118 reads (64%) | called by muse, mutect2, varscan2
- PDK4 | c.*1224A>C | 3'UTR (SNP) | VAF 65/168 reads (39%) | called by muse, mutect2, varscan2
- PDZD3 | c.*31G>C | 3'UTR (SNP) | VAF 112/357 reads (31%) | catalogued as COSV100501407; called by muse, mutect2, varscan2
- PHACTR1 | c.1448-19T>A | Intron (SNP) | VAF 74/117 reads (63%) | called by muse, mutect2, varscan2
- PIP5KL1 | c.*535A>C | 3'UTR (SNP) | VAF 77/127 reads (61%) | called by muse, mutect2, varscan2
- PLPPR5 | c.*800C>G | 3'UTR (SNP) | VAF 28/62 reads (45%) | called by muse, mutect2, varscan2
- PPARGC1A | c.*1397A>G | 3'UTR (SNP) | VAF 38/83 reads (46%) | called by muse, mutect2, varscan2
- PPARGC1B | c.*279G>A | 3'UTR (SNP) | VAF 220/325 reads (68%) | catalogued as rs897830401; called by muse, mutect2, varscan2
- PPID | c.-39_-38dup | 5'UTR (INS) | VAF 19/141 reads (13%) | called by mutect2, pindel, varscan2
- PTCH1 | c.585-30A>T | Intron (SNP) | VAF 7/96 reads (7%) | called by muse, mutect2
- PTOV1 | chr19:49851017 C>A | 5'Flank (SNP) | VAF 113/170 reads (66%) | called by muse, mutect2, varscan2
- PTPRN2 | c.2344+4610C>T | Intron (SNP) | VAF 103/174 reads (59%) | catalogued as rs151073371; called by muse, mutect2, varscan2
- RAP2B | c.*1550G>C | 3'UTR (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2
- RFX6 | c.-14C>T | 5'UTR (SNP) | VAF 58/98 reads (59%) | called by muse, mutect2, varscan2
- RGS16 | c.*643C>T | 3'UTR (SNP) | VAF 72/119 reads (61%) | catalogued as rs945475719; called by muse, mutect2, varscan2
- RHBDD1 | c.655+58T>G | Intron (SNP) | VAF 235/378 reads (62%) | catalogued as rs1426145536; called by muse, mutect2, varscan2
- RNF19A | c.*700del | 3'UTR (DEL) | VAF 22/110 reads (20%) | called by mutect2, pindel, varscan2
- S1PR3 | c.-147-354G>T | Intron (SNP) | VAF 41/143 reads (29%) | called by muse, mutect2, varscan2
- SCRT2 | c.*2024C>A | 3'UTR (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
- SEC61G | chr7:54759234 del C | 5'Flank (DEL) | VAF 161/330 reads (49%) | catalogued as COSV61855745; called by mutect2, pindel, varscan2
- SEC62 | c.*5204_*5206del | 3'UTR (DEL) | VAF 58/109 reads (53%) | catalogued as rs138394050; called by pindel, varscan2
- SFMBT2 | c.*2002C>T | 3'UTR (SNP) | VAF 28/74 reads (38%) | called by muse, mutect2, varscan2
- SH2D3C | c.515+2707G>A | Intron (SNP) | VAF 38/162 reads (23%) | called by muse, mutect2, varscan2
- SKI | c.*835C>T | 3'UTR (SNP) | VAF 18/105 reads (17%) | catalogued as rs528280335; called by muse, mutect2, varscan2
- SLC26A1 | c.*1149C>G | 3'UTR (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- SLC5A12 | c.*2527A>C | 3'UTR (SNP) | VAF 54/143 reads (38%) | called by muse, mutect2, varscan2
- SOCS4 | c.*3304T>G | 3'UTR (SNP) | VAF 37/64 reads (58%) | called by muse, mutect2, varscan2
- SPCS3 | c.*3209A>T | 3'UTR (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
- SVIP | c.*983T>A | 3'UTR (SNP) | VAF 12/39 reads (31%) | called by muse, mutect2, varscan2
- THAP5 | c.80+75T>C | Intron (SNP) | VAF 53/186 reads (28%) | catalogued as rs1182403174; called by muse, mutect2, varscan2
- THEMIS | c.*599T>G | 3'UTR (SNP) | VAF 26/70 reads (37%) | called by muse, mutect2, varscan2
- THUMPD1 | c.407-292C>T | Intron (SNP) | VAF 23/54 reads (43%) | catalogued as rs147690825; called by muse, mutect2, varscan2
- TM7SF2 | c.603+12T>C | Intron (SNP) | VAF 14/47 reads (30%) | called by muse, mutect2, varscan2
- TMC3 | c.1716-138T>C | Intron (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- TMEM106B | c.*4130C>T | 3'UTR (SNP) | VAF 17/78 reads (22%) | called by muse, mutect2, varscan2
- TMEM184A | c.*326C>G | 3'UTR (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- TMEM30A | c.*1015T>C | 3'UTR (SNP) | VAF 71/113 reads (63%) | called by muse, mutect2, varscan2
- TSN | c.*1501C>A | 3'UTR (SNP) | VAF 26/108 reads (24%) | called by muse, mutect2, varscan2
- TSPAN9 | c.*1559A>G | 3'UTR (SNP) | VAF 92/131 reads (70%) | called by muse, mutect2, varscan2
- TTN | c.25810+92G>A | Intron (SNP) | VAF 26/108 reads (24%) | catalogued as rs1454022191; called by muse, mutect2, varscan2
- TXNIP | c.*1341_*1347del | 3'UTR (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel
- UBE2H | c.-337C>A | 5'UTR (SNP) | VAF 82/120 reads (68%) | called by muse, mutect2, varscan2
- UHRF1BP1 | c.*3108A>G | 3'UTR (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- UNC13D | c.2447+161G>A | Intron (SNP) | VAF 88/277 reads (32%) | called by muse, mutect2, varscan2
- VPS33A | c.*55A>C | 3'UTR (SNP) | VAF 51/71 reads (72%) | called by muse, mutect2, varscan2
- WBP1L | c.*1623C>T | 3'UTR (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- WHRN | c.1167-217C>T | Intron (SNP) | VAF 23/45 reads (51%) | called by muse, mutect2, varscan2
- WIPI2 | c.*623G>T | 3'UTR (SNP) | VAF 24/81 reads (30%) | called by muse, mutect2, varscan2
- WNT7B | c.*1784C>T | 3'UTR (SNP) | VAF 98/207 reads (47%) | called by muse, mutect2, varscan2
- WNT9B | chr17:46885035 T>C | 3'Flank (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- ZNF717 | c.*101A>C | 3'UTR (SNP) | VAF 121/183 reads (66%) | called by muse, mutect2, varscan2
- ZSWIM9 | c.276-72A>G | Intron (SNP) | VAF 13/25 reads (52%) | called by muse, mutect2, varscan2
